Somatic mutation profile of tumor specimen C3L-03681-03 (aliquot CPT0221180005) from CPTAC case C3L-03681, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.8 years (22,946 days).
Specimen C3L-03681-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf35686a-3930-45ce-b51f-b4a316301a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03681-31 (Blood Derived Normal), aliquot CPT0220510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a90aa36f-dfe3-42a1-acfe-3db6e09d6a75

The open-access MAF lists 52 somatic variants for this specimen: 31 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 15, Intron 2, 5'Flank 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG5 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 117/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755744648; called by muse, mutect2, varscan2
- AGXT2 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV51490008, COSV51490695; called by muse, mutect2, varscan2
- ASZ1 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 99/523 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.822); catalogued as rs777726233, COSV52912406; called by muse, mutect2, varscan2
- FER1L6 | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV67552269; called by muse, mutect2, varscan2
- KDR | c.1091G>T p.W364L | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs368979581; called by muse, mutect2, varscan2
- MAP3K4 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62338721; called by muse, mutect2, varscan2
- NRG1 | c.1624G>A p.A542T (on ENST00000405005 / NM_013964.5; = p.A547T on NM_013956.5) | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776391266, COSV55154820; called by muse, mutect2, varscan2
- OR51T1 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs750968063; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.290C>T p.A97V (on ENST00000259318 / NM_001136562.3; = p.A328V on NM_007203.5) | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs147894013; called by muse, mutect2, varscan2
- PTEN | c.1026+1del | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs398123313, CM132269, COSV100911310, COSV64292596, COSV64307072; called by mutect2, pindel, varscan2
- RETNLB | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99848904; called by muse, mutect2, varscan2
- RUNDC3A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs1417453697, COSV56637017; called by muse, mutect2, varscan2
- SLC10A6 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.384); catalogued as rs201421765, COSV56721514; called by muse, mutect2, varscan2
- SLC32A1 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1464822213; called by muse, mutect2, varscan2
- SLC52A2 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs782549718; called by muse, mutect2, varscan2
- SLC5A2 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 169/515 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768579234; called by muse, mutect2, varscan2
- STYXL2 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs573913763, COSV99068450; called by muse, varscan2
- ZNF443 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs775956372; called by muse, mutect2, varscan2
- AIFM3 | c.949A>T p.I317F | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- AMZ2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARR3 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- CYLC2 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC1 | c.4657T>G p.L1553V (on ENST00000597505 / NM_001367979.1; = p.L660V on NM_020869.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KCNA6 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 278/511 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KIAA2012 | c.2849G>A p.W950* | Nonsense Mutation (SNP) | VAF 96/305 reads (31%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.3377A>G p.Y1126C | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ZDHHC9 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF532 | c.3105G>A p.M1035I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); called by mutect2, varscan2
- ZNF682 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF786 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF831 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACSM5 | c.105C>T p.I35= | Silent (SNP) | VAF 194/566 reads (34%) | catalogued as rs761085728, COSV59371645; called by muse, mutect2, varscan2
- ADGRV1 | c.1065T>C p.A355= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs1257314927; called by muse, mutect2, varscan2
- ANKRD52 | c.2025G>A p.G675= | Silent (SNP) | VAF 71/144 reads (49%) | called by muse, mutect2, varscan2
- CPAMD8 | c.429C>T p.G143= (on ENST00000651564; = p.G96= on NM_015692.5) | Silent (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- GALM | c.849C>A p.G283= | Silent (SNP) | VAF 67/391 reads (17%) | called by muse, mutect2, varscan2
- HYAL4 | c.720C>T p.D240= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs757517314; called by muse, mutect2, varscan2
- KRT1 | c.1719C>T p.G573= | Silent (SNP) | VAF 44/622 reads (7%) | catalogued as COSV99358490; called by muse, mutect2
- MUC4 | c.10584A>G p.S3528= | Silent (SNP) | VAF 78/822 reads (9%) | catalogued as rs1324464583; called by muse, mutect2
- OTUB2 | c.585C>T p.Y195= | Silent (SNP) | VAF 151/283 reads (53%) | catalogued as rs564363743; called by muse, mutect2, varscan2
- PEG10 | c.912C>T p.Y304= (on ENST00000482108 / NM_001040152.2; = p.Y338= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV71788715; called by muse, mutect2, varscan2
- SP4 | c.2157T>C p.S719= | Silent (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2
- TLR7 | c.813G>A p.A271= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as rs201564398, COSV66124165; called by muse, mutect2, varscan2
- TRAV12-1 | c.108G>A p.E36= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- VPS8 | c.3201A>G p.Q1067= (on ENST00000625842 / NM_001349294.1; = p.Q1065= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- ZFR2 | c.279C>T p.Y93= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs758708543; called by muse, mutect2, varscan2
- DLST | c.146+16G>C | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, varscan2
- HERC2P3 | n.482C>G | RNA (SNP) | VAF 108/1132 reads (10%) | called by muse, mutect2
- IGHD2-2 | chr14:105921175 C>T | 5'Flank (SNP) | VAF 119/248 reads (48%) | catalogued as rs200524316; called by muse, mutect2, varscan2
- MAGEA4 | chrX:151912441 A>G | 5'Flank (SNP) | VAF 60/176 reads (34%) | called by muse, mutect2, varscan2
- OPN5 | c.*12C>T | 3'UTR (SNP) | VAF 22/55 reads (40%) | catalogued as rs1490905051; called by muse, mutect2, varscan2
- RBM46 | c.1403-1049G>A | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as rs1052117842; called by muse, mutect2, varscan2
